Somatic mutation profile of tumor specimen TCGA-EL-A3ZT-01A (aliquot TCGA-EL-A3ZT-01A-12D-A23M-08) from TCGA case TCGA-EL-A3ZT, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 35.9 years (13,103 days).
Specimen TCGA-EL-A3ZT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24b3e988-b959-4963-a2c8-8494e3e1a50f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3ZT-11A (Solid Tissue Normal), aliquot TCGA-EL-A3ZT-11A-13D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9626a995-1d8b-40b9-a423-131072aa75b5

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CAPN15 | c.2075T>C p.M692T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54834179; called by muse, mutect2, varscan2
- MED13L | c.5420A>G p.D1807G | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs1387419880, COSV56115719; called by muse, mutect2
- PTPN4 | c.898G>C p.A300P | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV99749822, COSV99749911; called by muse, mutect2, varscan2
- PTPN4 | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV99749825; called by muse, mutect2, varscan2
- TFE3 | c.359T>G p.L120R | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59945911; called by muse, mutect2, varscan2
- TRIO | c.7690G>A p.A2564T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59988595; called by muse, mutect2, varscan2
- ZC3H4 | c.2252G>T p.R751L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs372785889, COSV53410475; called by muse, mutect2, varscan2
- WNT3A | c.177C>T p.Y59= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs745929272, COSV52728411; called by muse, mutect2, varscan2
